CCDI case PBBSJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8558c75a-dd38-4643-a1b7-b01bbb53106b

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 5.3 years (1,947 days).

Biospecimens (3 samples)
- Sample 0DFKHQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFKHR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFKHT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
